Somatic mutation profile of tumor specimen C3N-02030-01 (aliquot CPT0133760083) from CPTAC case C3N-02030, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 62.7 years (22,893 days).
Specimen C3N-02030-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 305eefc4-0882-47d3-ae0c-6f38d9b0f6fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02030-71 (Blood Derived Normal), aliquot CPT0133880002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9f746fd2-fac3-4033-9c1c-25c932390587

The open-access MAF lists 662 somatic variants for this specimen: 444 protein-altering or splice-affecting, 136 silent, 82 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 294, Silent 136, Frame Shift Del 89, Intron 36, Frame Shift Ins 23, Nonsense Mutation 18, 3'UTR 17, 5'UTR 12, RNA 9, Splice Site 8, 5'Flank 6, In Frame Del 6.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>A p.S37Y | Missense Mutation (SNP) | VAF 93/233 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FGFR2 | c.755C>G p.S252W | Missense Mutation (SNP) | VAF 64/121 reads (53%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs79184941, CM950458, CM970526, COSV60638319; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- GRM1 | c.26dup p.A11Sfs*78 | Frame Shift Ins (INS) | VAF 126/378 reads (33%) | catalogued as rs758809498; ClinVar: pathogenic; called by mutect2, varscan2
- HIBCH | c.129del p.G44Vfs*6 | Frame Shift Del (DEL) | VAF 17/140 reads (12%) | catalogued as rs767597690; ClinVar: pathogenic; called by mutect2, varscan2
- JAG1 | c.311del p.G104Afs*57 | Frame Shift Del (DEL) | VAF 104/310 reads (34%) | catalogued as rs886041782; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MLH1 | c.1489dup p.R497Pfs*6 | Frame Shift Ins (INS) | VAF 76/264 reads (29%) | catalogued as rs63750855; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.103A>G p.M35V | Missense Mutation (SNP) | VAF 34/114 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs876659443, CM110119, COSV64289131, COSV64291926, COSV64310633; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 148/303 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TECTA | c.5977C>T p.R1993* | Nonsense Mutation (SNP) | VAF 65/175 reads (37%) | catalogued as rs760574657; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A4GNT | c.4C>T p.R2W | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as rs755655007, COSV99367987; called by muse, mutect2
- ABCA8 | c.4036G>A p.V1346M | Missense Mutation (SNP) | VAF 94/192 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs767871494, COSV52201017; called by muse, mutect2, varscan2
- ABCB9 | c.1672del p.L558Wfs*24 (on ENST00000280560 / NM_019625.4; = p.L515Wfs*24 on NM_019624.3) | Frame Shift Del (DEL) | VAF 66/214 reads (31%) | catalogued as rs1334723787; called by mutect2, pindel, varscan2
- ABCC1 | c.2656G>A p.V886I | Missense Mutation (SNP) | VAF 77/185 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs756648375; called by muse, mutect2, varscan2
- ACOT7 | c.1090C>T p.R364W (on ENST00000377855 / NM_181864.3; = p.R354W on NM_007274.4) | Missense Mutation (SNP) | VAF 38/338 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781024703, COSV64111974; called by muse, mutect2, varscan2
- ADAM8 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 92/389 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); catalogued as rs1027697833; called by muse, mutect2, varscan2
- AEBP1 | c.2383del p.E795Rfs*32 | Frame Shift Del (DEL) | VAF 117/388 reads (30%) | catalogued as COSV56260153; called by mutect2, pindel, varscan2
- AGO2 | c.1806del p.A603Pfs*92 | Frame Shift Del (DEL) | VAF 56/196 reads (29%) | catalogued as rs748399150; called by mutect2, pindel, varscan2
- AKAP8 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as rs537526016; called by muse, mutect2, varscan2
- ALDH7A1 | c.1061A>T p.Y354F | Missense Mutation (SNP) | VAF 80/210 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as CM121731; called by muse, mutect2, varscan2
- ANKRD11 | c.6859G>A p.G2287S | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.001); catalogued as rs775584042; called by muse, mutect2, varscan2
- ANKRD18A | c.1826A>G p.Q609R | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.403); catalogued as rs1349473073; called by muse, mutect2, varscan2
- AOX1 | c.3902C>T p.T1301I | Missense Mutation (SNP) | VAF 52/174 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs758532219; called by muse, mutect2, varscan2
- APC2 | c.1964G>A p.R655H | Missense Mutation (SNP) | VAF 106/250 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.664); catalogued as rs1476993748; called by muse, mutect2, varscan2
- APEX2 | c.1030G>T p.V344F | Missense Mutation (SNP) | VAF 70/159 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs1374661061; called by muse, mutect2, varscan2
- APOA5 | c.398C>T p.T133M | Missense Mutation (SNP) | VAF 213/547 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM120394; called by muse, mutect2, varscan2
- ASPM | c.6028G>A p.G2010R | Missense Mutation (SNP) | VAF 40/172 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.677); catalogued as rs1327528392; called by muse, mutect2, varscan2
- ASTN2 | c.584C>T p.S195L | Missense Mutation (SNP) | VAF 18/274 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.083); catalogued as rs747198436, COSV100530346, COSV57775494; called by muse, mutect2
- ATP2B3 | c.2132C>T p.T711M | Missense Mutation (SNP) | VAF 117/325 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99051133; called by muse, mutect2, varscan2
- B3GAT1 | c.664G>A p.V222M | Missense Mutation (SNP) | VAF 71/165 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs763308287; called by muse, mutect2, varscan2
- BCL10 | c.73C>T p.R25C | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV65354068; called by muse, mutect2, varscan2
- BLK | c.107C>T p.P36L | Missense Mutation (SNP) | VAF 37/213 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as rs1013048438, COSV52056498; called by muse, mutect2, varscan2
- BMPR1B | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs373000965; called by muse, mutect2, varscan2
- BRD8 | c.2250-3del | Splice Region (DEL) | VAF 9/32 reads (28%) | catalogued as rs749043197; called by mutect2, varscan2
- CACNB1 | c.1460G>A p.R487Q | Missense Mutation (SNP) | VAF 64/133 reads (48%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as rs753711036; called by muse, mutect2, varscan2
- CCDC130 | c.401-8C>T | Splice Region (SNP) | VAF 91/247 reads (37%) | catalogued as rs374818294; called by muse, mutect2, varscan2
- CCDC7 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1055718131, COSV99511956; called by muse, mutect2, varscan2
- CD59 | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 73/246 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.044); catalogued as COSV100681242; called by muse, mutect2, varscan2
- CEBPA | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 239/600 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs781549846; called by muse, mutect2, varscan2
- CKLF | c.447dup p.E150Rfs*12 (on ENST00000264001 / NM_016951.4; = p.E65Rfs*12 on NM_016326.3) | Frame Shift Ins (INS) | VAF 28/182 reads (15%) | catalogued as rs754415052; called by mutect2, varscan2
- COL14A1 | c.1321+1G>A p.X441_splice | Splice Site (SNP) | VAF 15/44 reads (34%) | catalogued as rs775204866, COSV52852671; called by muse, mutect2, varscan2
- COL18A1 | c.4289del p.P1430Lfs*16 (on ENST00000359759 / NM_130444.3; = p.P1195Lfs*16 on NM_030582.4) | Frame Shift Del (DEL) | VAF 228/534 reads (43%) | catalogued as rs748210520; called by mutect2, varscan2
- COL27A1 | c.1781C>T p.P594L | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as rs781277879, COSV61925278; called by muse, mutect2, varscan2
- COL5A1 | c.2153G>C p.G718A | Missense Mutation (SNP) | VAF 18/552 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as COSV104425761; called by muse, mutect2
- CPAMD8 | c.1994C>T p.A665V (on ENST00000651564; = p.A618V on NM_015692.5) | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.018); catalogued as COSV52234755; called by muse, mutect2, varscan2
- CPT1C | c.1330C>T p.R444W | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs1481092171; called by muse, mutect2, varscan2
- CREBRF | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 54/117 reads (46%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as rs753152974, COSV51633080; called by muse, mutect2, varscan2
- CWF19L2 | c.977del p.N326Ifs*19 | Frame Shift Del (DEL) | VAF 14/50 reads (28%) | catalogued as COSV56519025; called by mutect2, pindel, varscan2
- CYP4V2 | c.769_770del p.S257Pfs*14 | Frame Shift Del (DEL) | VAF 46/173 reads (27%) | catalogued as rs767723431; called by pindel, varscan2
- DAPK3 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 57/108 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as rs756550520, COSV56662684; called by muse, mutect2, varscan2
- DBH | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 174/413 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as rs199566547; called by muse, mutect2, varscan2
- DENND2C | c.848G>A p.R283Q | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.801); catalogued as rs368033699; called by muse, mutect2
- DISP3 | c.1010G>A p.S337N | Missense Mutation (SNP) | VAF 24/184 reads (13%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.99); catalogued as rs1235080805; called by muse, varscan2
- DMBT1 | c.7462C>T p.R2488C (on ENST00000338354 / NM_001377530.1; = p.R1731C on NM_004406.3) | Missense Mutation (SNP) | VAF 146/538 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as rs1437407547; called by muse, mutect2, varscan2
- DOCK5 | c.966del p.F322Lfs*5 | Frame Shift Del (DEL) | VAF 34/90 reads (38%) | catalogued as rs36119599; called by mutect2, pindel, varscan2
- DPYSL4 | c.1144G>A p.A382T | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as rs374822669; called by muse, mutect2, varscan2
- DUSP4 | c.1120G>A p.V374M | Missense Mutation (SNP) | VAF 44/262 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.11); catalogued as rs552819707; called by muse, mutect2, varscan2
- DZIP3 | c.2694-1G>A p.X898_splice | Splice Site (SNP) | VAF 29/76 reads (38%) | catalogued as rs1420268774; called by muse, mutect2, varscan2
- ELF4 | c.1456C>T p.L486F | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as COSV57452606; called by muse, mutect2, varscan2
- EPB41L5 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1414991675, COSV55354222; called by muse, mutect2
- ERLIN2 | c.631C>T p.R211W | Missense Mutation (SNP) | VAF 74/439 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs374289791; called by muse, mutect2, varscan2
- FAM131B | c.863C>T p.A288V | Missense Mutation (SNP) | VAF 157/419 reads (37%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs759366087, COSV58367322, COSV58375458; called by muse, mutect2, varscan2
- FANCC | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as COSV56658871; called by muse, mutect2, varscan2
- FASN | c.4655G>A p.R1552H | Missense Mutation (SNP) | VAF 85/217 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as rs774834763, COSV60760160; called by muse, mutect2, varscan2
- FBXL19 | c.763G>A p.G255S | Missense Mutation (SNP) | VAF 22/340 reads (6%) | SIFT tolerated (0.75); PolyPhen benign (0.198); catalogued as rs373602730; called by muse, mutect2
- FLG | c.5852G>A p.R1951K | Missense Mutation (SNP) | VAF 193/935 reads (21%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.677); catalogued as COSV64242052; called by muse, mutect2, varscan2
- FOXD3 | c.1178G>A p.G393D | Missense Mutation (SNP) | VAF 73/181 reads (40%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.074); catalogued as rs943720041; called by muse, mutect2, varscan2
- FRYL | c.989del p.L330* | Frame Shift Del (DEL) | VAF 16/64 reads (25%) | catalogued as rs1348158626; called by mutect2, varscan2
- FSCN2 | c.1071_1073del p.K357del | In Frame Del (DEL) | VAF 67/224 reads (30%) | catalogued as rs760309853; called by pindel, varscan2
- FSCN3 | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 91/287 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs182430717; called by muse, mutect2, varscan2
- FUBP1 | c.1345-5del | Splice Region (DEL) | VAF 40/120 reads (33%) | catalogued as rs545766306; called by mutect2, varscan2
- FZD7 | c.1609A>G p.T537A | Missense Mutation (SNP) | VAF 93/272 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.036); catalogued as rs1342968635; called by muse, mutect2, varscan2
- GBE1 | c.2011del p.S671Lfs*36 | Frame Shift Del (DEL) | VAF 14/52 reads (27%) | catalogued as rs780374709; called by mutect2, pindel, varscan2
- GDF6 | c.1303G>A p.A435T | Missense Mutation (SNP) | VAF 113/297 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV54625250, COSV54626250; called by muse, mutect2, varscan2
- GPAM | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 85/340 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs760239867, COSV62081256; called by muse, mutect2, varscan2
- GPM6A | c.805C>T p.R269C | Missense Mutation (SNP) | VAF 8/143 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54548237, COSV99702946; called by muse, mutect2
- GRIN2C | c.1624G>A p.V542I | Missense Mutation (SNP) | VAF 88/260 reads (34%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.99); catalogued as rs1475521396; called by muse, mutect2, varscan2
- GRM7 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 112/333 reads (34%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.992); catalogued as rs761616232; called by muse, mutect2, varscan2
- HEBP2 | c.593dup p.N198Kfs*2 | Frame Shift Ins (INS) | VAF 24/66 reads (36%) | catalogued as rs769528102; called by mutect2, varscan2
- HNRNPA1 | c.18T>G p.S6= | Splice Region (SNP) | VAF 29/85 reads (34%) | catalogued as rs755898648; called by muse, mutect2, varscan2
- HOXB9 | c.590C>A p.T197K | Missense Mutation (SNP) | VAF 90/212 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60817538; called by muse, mutect2, varscan2
- HPCA | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 133/332 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as rs749485354, COSV65103324; called by muse, mutect2, varscan2
- HPS1 | c.1646G>A p.R549H | Missense Mutation (SNP) | VAF 167/631 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753635327, COSV57268666; called by muse, mutect2, varscan2
- HS6ST2 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 12/337 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV63715440; called by muse, mutect2
- HTR1F | c.930del p.F310Lfs*2 | Frame Shift Del (DEL) | VAF 13/43 reads (30%) | catalogued as rs748579647; called by mutect2, pindel, varscan2
- IARS2 | c.69del p.T24Rfs*50 | Frame Shift Del (DEL) | VAF 38/210 reads (18%) | catalogued as COSV56964106; called by mutect2, pindel
- IFI44L | c.204T>A p.N68K | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.91); PolyPhen benign (0.067); catalogued as rs1183417767; called by muse, mutect2, varscan2
- IGF1 | c.579del p.G194Efs*8 | Frame Shift Del (DEL) | VAF 34/107 reads (32%) | catalogued as rs1565968684, COSV61032034; called by mutect2, pindel, varscan2
- IRX5 | c.278T>C p.M93T | Missense Mutation (SNP) | VAF 53/140 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs769740301; called by muse, mutect2, varscan2
- ITLN1 | c.512C>T p.T171M | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370631307, COSV58273846; called by muse, mutect2, varscan2
- KANK4 | c.280G>A p.V94M | Missense Mutation (SNP) | VAF 128/337 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.017); catalogued as rs373246857, COSV62986738; called by muse, mutect2, varscan2
- KATNIP | c.215A>G p.Y72C | Missense Mutation (SNP) | VAF 82/206 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766133134; called by muse, mutect2, varscan2
- KBTBD7 | c.167_169del p.F56del | In Frame Del (DEL) | VAF 132/359 reads (37%) | catalogued as rs1418828287; called by mutect2, pindel, varscan2
- KCNA4 | c.663del p.F221Lfs*21 | Frame Shift Del (DEL) | VAF 24/154 reads (16%) | catalogued as rs754892524; called by mutect2, pindel, varscan2
- KCNH3 | c.2123del p.G708Efs*11 | Frame Shift Del (DEL) | VAF 88/236 reads (37%) | catalogued as rs1229306184; called by mutect2, pindel, varscan2
- KLHL26 | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0.351); catalogued as rs749078539; called by muse, mutect2, varscan2
- KMT2D | c.5927C>T p.S1976L | Missense Mutation (SNP) | VAF 71/129 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV56468464; called by muse, mutect2, varscan2
- KSR1 | c.2042C>T p.T681M (on ENST00000644974 / NM_001367810.1; = p.T566M on NM_014238.2) | Missense Mutation (SNP) | VAF 57/217 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.633); catalogued as rs1363963229, COSV99258826; called by muse, mutect2, varscan2
- LAGE3 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 53/123 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.117); catalogued as COSV62074504; called by muse, mutect2, varscan2
- LRRC53 | c.1424T>C p.I475T | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1322380211; called by muse, mutect2, varscan2
- LTB | c.173C>T p.T58M | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as rs567302751, COSV53000420; called by muse, mutect2, varscan2
- MAN2C1 | c.2983C>T p.Q995* | Nonsense Mutation (SNP) | VAF 106/299 reads (35%) | catalogued as COSV99145269; called by muse, mutect2, varscan2
- MED13L | c.3686T>A p.L1229H | Missense Mutation (SNP) | VAF 96/225 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99928480; called by muse, mutect2, varscan2
- MEDAG | c.206del p.G69Afs*29 | Frame Shift Del (DEL) | VAF 33/218 reads (15%) | catalogued as rs745558596; called by mutect2, pindel, varscan2
- MPDU1 | c.446C>T p.T149M | Missense Mutation (SNP) | VAF 153/466 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs764397720; called by muse, mutect2, varscan2
- MTERF3 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs750850029; called by muse, mutect2, varscan2
- MUC17 | c.12128G>A p.R4043H | Missense Mutation (SNP) | VAF 37/243 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.046); catalogued as rs147525614; called by muse, mutect2, varscan2
- MYLK | c.4813G>T p.D1605Y | Missense Mutation (SNP) | VAF 175/406 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60610051; called by muse, mutect2, varscan2
- MYO3A | c.3341C>T p.T1114I | Missense Mutation (SNP) | VAF 29/141 reads (21%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV56352031; called by muse, mutect2, varscan2
- MYO3A | c.3574dup p.M1192Nfs*3 | Frame Shift Ins (INS) | VAF 37/156 reads (24%) | catalogued as rs757810767; called by mutect2, varscan2
- NFX1 | c.1441C>T p.R481* | Nonsense Mutation (SNP) | VAF 34/100 reads (34%) | catalogued as rs1451971621; called by muse, mutect2, varscan2
- NIPBL | c.2171C>A p.T724N | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.107); catalogued as COSV56959792; called by muse, mutect2, varscan2
- NKX6-2 | c.358G>A p.G120S | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as rs1447090832; called by muse, mutect2, varscan2
- NR1D1 | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 72/206 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52843337; called by muse, mutect2, varscan2
- NR2C2 | c.1689del p.F563Lfs*10 (on ENST00000393102; = p.F582Lfs*10 on NM_003298.5) | Frame Shift Del (DEL) | VAF 30/89 reads (34%) | catalogued as rs774343392; called by mutect2, varscan2
- NRBP2 | c.1361T>C p.L454P | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as rs1554651582; called by muse, mutect2, varscan2
- NRROS | c.680G>A p.R227Q | Missense Mutation (SNP) | VAF 76/177 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751058757, COSV60744792; called by muse, mutect2, varscan2
- NUDT22 | c.225del p.P76Hfs*52 | Frame Shift Del (DEL) | VAF 107/299 reads (36%) | catalogued as rs755949538; called by mutect2, pindel, varscan2
- ODF3L2 | c.49dup p.L17Pfs*62 | Frame Shift Ins (INS) | VAF 50/134 reads (37%) | catalogued as rs748636054; called by mutect2, pindel, varscan2
- OR52A5 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as rs1221037254, COSV56615866; called by muse, mutect2, varscan2
- OR5B2 | c.404C>T p.T135M | Missense Mutation (SNP) | VAF 54/113 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.393); catalogued as rs199556711; called by muse, mutect2, varscan2
- PAXIP1 | c.300del p.F100Lfs*31 | Frame Shift Del (DEL) | VAF 13/38 reads (34%) | catalogued as rs753190856; called by mutect2, varscan2
- PBRM1 | c.1730A>G p.N577S | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs115997236; called by muse, mutect2, varscan2
- PCDHA5 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 151/404 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.232); catalogued as COSV65352687, COSV65353320, COSV65354029; called by muse, varscan2
- PCDHB16 | c.1921G>T p.V641L | Missense Mutation (SNP) | VAF 199/509 reads (39%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV53360912; called by muse, mutect2, varscan2
- PCDHGB1 | c.536C>T p.T179M | Missense Mutation (SNP) | VAF 56/126 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.041); catalogued as rs780182840, COSV53893504, COSV54007624; called by muse, mutect2, varscan2
- PDE2A | c.2266C>T p.R756C | Missense Mutation (SNP) | VAF 85/186 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs138870390, COSV57811844; called by muse, mutect2, varscan2
- PGAM5 | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 59/222 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768706336; called by muse, mutect2, varscan2
- PHACTR4 | c.160del p.S54Vfs*12 (on ENST00000373839 / NM_001350159.2; = p.S64Vfs*12 on NM_023923.4) | Frame Shift Del (DEL) | VAF 28/100 reads (28%) | catalogued as rs761437290, COSV65783432; called by mutect2, varscan2
- PHACTR4 | c.2032G>T p.E678* (on ENST00000373839 / NM_001350159.2; = p.E688* on NM_023923.4) | Nonsense Mutation (SNP) | VAF 25/80 reads (31%) | catalogued as COSV65783415, COSV65785417; called by muse, mutect2, varscan2
- PIK3C2B | c.247G>A p.G83S | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.009); catalogued as rs373236355; called by muse, mutect2, varscan2
- PLD6 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as rs772007129, COSV58634239; called by muse, mutect2, varscan2
- PLEKHM1 | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 104/344 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1251964349, COSV69598825; called by muse, mutect2, varscan2
- PLXNB3 | c.5080A>G p.T1694A | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1249993822; called by muse, mutect2, varscan2
- PMFBP1 | c.1937G>T p.R646L (on ENST00000537465; = p.R641L on NM_031293.3) | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.363); catalogued as COSV52822054, COSV52825354; called by muse, mutect2, varscan2
- PNPLA7 | c.2233G>A p.A745T | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.018); catalogued as rs149697052; called by muse, mutect2, varscan2
- PODXL | c.541C>A p.P181T | Missense Mutation (SNP) | VAF 136/383 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs758337217, COSV59872367; called by muse, mutect2, varscan2
- POLD1 | c.2789C>T p.A930V | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.188); catalogued as rs1060501855; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPRC1 | c.2819del p.P940Hfs*6 | Frame Shift Del (DEL) | VAF 42/154 reads (27%) | catalogued as rs768056539; called by mutect2, varscan2
- PROC | c.1212del p.M406Wfs*15 | Frame Shift Del (DEL) | VAF 39/141 reads (28%) | catalogued as CM951029; called by mutect2, pindel, varscan2
- RAB11FIP5 | c.891del p.K298Sfs*109 | Frame Shift Del (DEL) | VAF 20/58 reads (34%) | catalogued as COSV99241854; called by mutect2, pindel, varscan2
- RANGAP1 | c.865C>T p.R289C | Missense Mutation (SNP) | VAF 101/237 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs771897708; called by muse, mutect2, varscan2
- RB1 | c.1959del p.V654Cfs*4 | Frame Shift Del (DEL) | VAF 20/64 reads (31%) | catalogued as CM1110478, COSV57298520; called by mutect2, pindel, varscan2
- RBM20 | c.3210del p.T1071Pfs*33 | Frame Shift Del (DEL) | VAF 92/436 reads (21%) | catalogued as COSV65705579; called by mutect2, pindel, varscan2
- REM1 | c.688C>T p.H230Y | Missense Mutation (SNP) | VAF 13/276 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52428744; called by muse, mutect2
- REV3L | c.4055C>T p.T1352M | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.425); catalogued as rs758477587, COSV62617192; called by muse, mutect2, varscan2
- RGS12 | c.3870del p.Q1292Rfs*49 | Frame Shift Del (DEL) | VAF 22/50 reads (44%) | catalogued as rs751982308; called by mutect2, varscan2
- RILP | c.1150T>C p.C384R | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.452); catalogued as COSV53961695; called by muse, mutect2, varscan2
- RNF11 | c.404C>T p.T135M | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1313459994, COSV99657934; called by muse, mutect2, varscan2
- ROBO3 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 75/408 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM090354; called by muse, varscan2
- RP1L1 | c.7144G>A p.A2382T | Missense Mutation (SNP) | VAF 122/329 reads (37%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs776156711, COSV66762092; called by muse, mutect2, varscan2
- RPL7L1 | c.460C>A p.L154M | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100491742; called by muse, mutect2, varscan2
- RTKN | c.193C>T p.R65* (on ENST00000272430 / NM_001015055.2; = p.R52* on NM_033046.2) | Nonsense Mutation (SNP) | VAF 65/341 reads (19%) | catalogued as rs532819376; called by muse, mutect2, varscan2
- RXFP1 | c.1823A>G p.Q608R | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs776423555; called by muse, varscan2
- S100PBP | c.92A>G p.E31G | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63140249; called by muse, mutect2
- SCARA3 | c.1513G>A p.G505R | Missense Mutation (SNP) | VAF 110/311 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760726180; called by muse, mutect2, varscan2
- SCNN1D | c.53del p.G18Afs*179 (on ENST00000338555; = p.A151Lfs*18 on NM_001130413.4) | Frame Shift Del (DEL) | VAF 8/53 reads (15%) | catalogued as rs1270083658; called by mutect2, pindel, varscan2
- SDAD1 | c.824del p.K275Rfs*15 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | catalogued as rs763181092; called by mutect2, pindel
- SDS | c.238G>A p.G80S | Missense Mutation (SNP) | VAF 9/234 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.363); catalogued as rs889529842; called by muse, mutect2
- SETD1B | c.4409C>T p.T1470M | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.584); catalogued as rs1490141875; called by muse, mutect2, varscan2
- SEZ6L2 | c.1691G>A p.R564H (on ENST00000308713 / NM_001114099.3; = p.R494H on NM_012410.4) | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1311011521, COSV58096855; called by muse, mutect2, varscan2
- SH2D5 | c.722G>A p.R241H (on ENST00000444387 / NM_001103161.2; = p.R157H on NM_001103160.2) | Missense Mutation (SNP) | VAF 120/357 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs766370454; called by muse, mutect2, varscan2
- SH3PXD2A | c.1645C>T p.R549W (on ENST00000369774 / NM_001365079.1; = p.R521W on NM_014631.2) | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.276); catalogued as rs751523064; called by muse, mutect2, varscan2
- SIGLEC12 | c.622C>A p.P208T (on ENST00000291707 / NM_053003.4; = p.P90T on NM_033329.2) | Missense Mutation (SNP) | VAF 95/224 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV52463588; called by muse, mutect2, varscan2
- SIPA1 | c.748_750del p.K250del | In Frame Del (DEL) | VAF 42/93 reads (45%) | catalogued as rs1333397145; called by mutect2, pindel, varscan2
- SIX4 | c.371del p.G124Afs*26 | Frame Shift Del (DEL) | VAF 61/197 reads (31%) | catalogued as COSV99381980; called by mutect2, pindel, varscan2
- SLC20A1 | c.1130A>C p.Q377P | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.796); catalogued as COSV55612374; called by muse, mutect2
- SLC25A30 | c.470G>A p.G157E | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs141801271; called by muse, mutect2, varscan2
- SMAD9 | c.787C>T p.R263* (on ENST00000379826 / NM_001127217.3; = p.R226* on NM_005905.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 61/189 reads (32%) | catalogued as rs1205054074, COSV63205853; called by muse, mutect2, varscan2
- SMAP1 | c.515del p.K172Rfs*48 (on ENST00000370455 / NM_001044305.3; = p.K145Rfs*48 on NM_021940.5) | Frame Shift Del (DEL) | VAF 36/72 reads (50%) | catalogued as rs763364024; called by mutect2, varscan2
- SMARCC2 | c.3268C>T p.P1090S | Missense Mutation (SNP) | VAF 125/359 reads (35%) | SIFT tolerated, low confidence (0.47); PolyPhen possibly damaging (0.901); catalogued as rs934469841; called by muse, mutect2, varscan2
- SMG6 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 26/161 reads (16%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.543); catalogued as rs777483170, COSV53966327; called by muse, mutect2, varscan2
- SNX25 | c.2086C>T p.R696* | Nonsense Mutation (SNP) | VAF 19/148 reads (13%) | catalogued as rs762094565, COSV53019082; called by muse, mutect2, varscan2
- SPEF2 | c.877dup p.I293Nfs*6 | Frame Shift Ins (INS) | VAF 14/83 reads (17%) | catalogued as rs1390109415; called by mutect2, varscan2
- SPRED2 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 10/232 reads (4%) | SIFT tolerated (0.68); PolyPhen benign (0.017); catalogued as COSV62694546; called by muse, mutect2
- SPTBN5 | c.5171G>A p.R1724Q | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as rs199701887; called by muse, mutect2, varscan2
- SVIL | c.5586del p.M1863Wfs*44 (on ENST00000355867 / NM_021738.3; = p.M1437Wfs*44 on NM_003174.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 23/90 reads (26%) | catalogued as rs770033147; called by mutect2, varscan2
- SYNE1 | c.10196G>A p.R3399Q (on ENST00000367255 / NM_182961.4; = p.R3406Q on NM_033071.3) | Missense Mutation (SNP) | VAF 69/202 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.32); catalogued as rs368647352; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TACC3 | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.03); catalogued as rs766595415; called by muse, mutect2, varscan2
- TAF1 | c.1877del p.K626Rfs*4 (on ENST00000373790 / NM_138923.4; = p.K647Rfs*4 on NM_004606.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 28/83 reads (34%) | catalogued as rs745516519; called by mutect2, varscan2
- TANC1 | c.4951T>C p.C1651R | Missense Mutation (SNP) | VAF 40/354 reads (11%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.1); catalogued as COSV55082619; called by muse, mutect2, varscan2
- TBC1D1 | c.928del p.I310* | Frame Shift Del (DEL) | VAF 27/78 reads (35%) | catalogued as rs760298745; called by mutect2, pindel, varscan2
- TDRKH | c.1474G>A p.A492T | Missense Mutation (SNP) | VAF 35/221 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767475622, COSV58617972; called by muse, mutect2, varscan2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 48/150 reads (32%) | catalogued as rs763321097; called by mutect2, varscan2
- TERF1 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs1563459421; called by muse, mutect2, varscan2
- TFCP2L1 | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 96/200 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55292626; called by muse, mutect2, varscan2
- TFEB | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as rs1289665036, COSV57826547; called by muse, mutect2, varscan2
- TMEM125 | c.47del p.P16Rfs*53 | Frame Shift Del (DEL) | VAF 28/61 reads (46%) | catalogued as rs1254012370; called by mutect2, pindel, varscan2
- TMEM63A | c.783G>C p.Q261H | Missense Mutation (SNP) | VAF 118/590 reads (20%) | SIFT tolerated (0.63); PolyPhen benign (0.015); catalogued as rs946138520; called by muse, mutect2, varscan2
- TOP3B | c.2470C>T p.R824C | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.425); catalogued as rs1270601428; called by mutect2, varscan2
- TRAV3 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 78/273 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs745851436; called by muse, mutect2, varscan2
- TRIM2 | c.1087G>A p.A363T (on ENST00000437508; = p.A390T on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); catalogued as rs754123914; called by muse, mutect2, varscan2
- TRIM31 | c.260A>G p.Q87R | Missense Mutation (SNP) | VAF 57/133 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs928628355; called by muse, mutect2, varscan2
- TRIM9 | c.475C>A p.Q159K | Missense Mutation (SNP) | VAF 190/415 reads (46%) | SIFT tolerated (0.52); PolyPhen benign (0.031); catalogued as COSV100030317; called by muse, mutect2, varscan2
- TRIO | c.7050del p.V2351Cfs*62 | Frame Shift Del (DEL) | VAF 31/91 reads (34%) | catalogued as rs746654944; called by mutect2, pindel, varscan2
- TRPM5 | c.1297C>T p.Q433* | Nonsense Mutation (SNP) | VAF 163/411 reads (40%) | catalogued as rs1467014210; called by muse, mutect2, varscan2
- TUBG2 | c.853G>A p.V285M | Missense Mutation (SNP) | VAF 84/219 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.853); catalogued as COSV52218597; called by muse, mutect2, varscan2
- ULK1 | c.1799G>A p.R600Q | Missense Mutation (SNP) | VAF 176/392 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.552); catalogued as rs745749590; called by muse, mutect2, varscan2
- USF3 | c.4640A>G p.Q1547R | Missense Mutation (SNP) | VAF 38/366 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.761); catalogued as rs772446982; called by muse, mutect2
- USP2 | c.825G>A p.T275= | Splice Region (SNP) | VAF 81/208 reads (39%) | catalogued as rs199771100; called by muse, mutect2, varscan2
- VPS33A | c.246del p.F82Lfs*6 | Frame Shift Del (DEL) | VAF 22/53 reads (42%) | catalogued as rs756221452; called by mutect2, varscan2
- VPS37D | c.712del p.L238Cfs*2 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | catalogued as rs1554609756; called by mutect2, pindel
- WDFY4 | c.316C>T p.Q106* | Nonsense Mutation (SNP) | VAF 18/318 reads (6%) | catalogued as COSV57439860; called by muse, mutect2
- XIRP1 | c.1228G>A p.G410S | Missense Mutation (SNP) | VAF 47/133 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs775595813, COSV100453679; called by muse, mutect2, varscan2
- ZBED1 | c.380C>T p.T127M | Missense Mutation (SNP) | VAF 122/281 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1308585565, COSV58134616; called by muse, mutect2, varscan2
- ZBED8 | c.894_897del p.N299Sfs*21 | Frame Shift Del (DEL) | VAF 46/108 reads (43%) | catalogued as rs1184980267; called by mutect2, pindel, varscan2
- ZBTB40 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 144/363 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs912482215; called by muse, mutect2, varscan2
- ZNF341 | c.2242dup p.Q748Pfs*22 (on ENST00000375200 / NM_001282935.1; = p.Q741Pfs*22 on NM_032819.4) | Frame Shift Ins (INS) | VAF 23/99 reads (23%) | catalogued as rs747874764; called by mutect2, varscan2
- ZNF467 | c.1312C>T p.R438C | Missense Mutation (SNP) | VAF 57/173 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100118113; called by muse, mutect2, varscan2
- ZNF48 | c.745dup p.R249Pfs*31 | Frame Shift Ins (INS) | VAF 48/140 reads (34%) | catalogued as rs780189754; called by mutect2, varscan2
- ZNF496 | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.184); catalogued as rs758982919, COSV54175637; called by muse, mutect2, varscan2
- ZSCAN2 | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 20/376 reads (5%) | SIFT tolerated (0.48); PolyPhen benign (0.017); catalogued as rs147069559; called by muse, mutect2
- ZSWIM4 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 66/172 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as rs145598293; called by mutect2, varscan2
- AADAT | c.566del p.N189Tfs*20 | Frame Shift Del (DEL) | VAF 43/136 reads (32%) | called by mutect2, pindel, varscan2
- ABCA13 | c.4595T>C p.M1532T | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.6); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ABI1 | c.286-1G>A p.X96_splice | Splice Site (SNP) | VAF 19/85 reads (22%) | called by muse, varscan2
- ACADSB | c.161T>C p.L54P | Missense Mutation (SNP) | VAF 46/180 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ACAP3 | c.1196G>A p.G399D | Missense Mutation (SNP) | VAF 239/592 reads (40%) | SIFT tolerated (0.61); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ACTR8 | c.1017T>A p.D339E | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ADAMTSL4 | c.1783del p.Y595Ifs*29 | Frame Shift Del (DEL) | VAF 86/535 reads (16%) | called by mutect2, pindel, varscan2
- ADGRE5 | c.2203G>A p.A735T (on ENST00000242786 / NM_078481.4; = p.A642T on NM_001784.5) | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- AHI1 | c.2791A>G p.K931E | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.079); called by muse, varscan2
- AHNAK2 | c.12265G>A p.A4089T | Missense Mutation (SNP) | VAF 247/650 reads (38%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- AHRR | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- AKAP4 | c.890G>A p.G297D | Missense Mutation (SNP) | VAF 49/159 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- AKAP9 | c.6111dup p.L2038Tfs*8 (on ENST00000359028; = p.L2006Tfs*8 on NM_005751.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 12/46 reads (26%) | called by mutect2, pindel, varscan2
- ANKRD31 | c.3134del p.L1045* | Frame Shift Del (DEL) | VAF 35/112 reads (31%) | called by mutect2, pindel, varscan2
- APOBR | c.2381A>G p.H794R (on ENST00000431282; = p.H803R on NM_018690.4) | Missense Mutation (SNP) | VAF 29/200 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARAP1 | c.2365G>A p.A789T (on ENST00000393609 / NM_001040118.2; = p.A544T on NM_015242.4) | Missense Mutation (SNP) | VAF 96/273 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ARHGAP18 | c.1877del p.L626Cfs*19 | Frame Shift Del (DEL) | VAF 26/91 reads (29%) | called by mutect2, pindel, varscan2
- ARHGAP4 | c.1784del p.P595Qfs*23 | Frame Shift Del (DEL) | VAF 12/93 reads (13%) | called by mutect2, varscan2
- ARHGAP4 | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 134/370 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- ARX | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ATP1A2 | c.1298C>T p.A433V | Missense Mutation (SNP) | VAF 118/556 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ATP2B4 | c.49A>C p.S17R | Missense Mutation (SNP) | VAF 71/279 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- B4GALNT4 | c.106G>A p.V36M | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- BSN | c.9295A>G p.S3099G | Missense Mutation (SNP) | VAF 27/190 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- C16orf89 | c.1120A>G p.T374A | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- C3orf20 | c.550G>A p.A184T | Missense Mutation (SNP) | VAF 100/280 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- C4orf54 | c.1462G>A p.A488T | Missense Mutation (SNP) | VAF 65/145 reads (45%) | SIFT tolerated, low confidence (0.25); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- CAMSAP2 | c.2786T>A p.V929E (on ENST00000236925 / NM_001297707.2; = p.V918E on NM_203459.3) | Missense Mutation (SNP) | VAF 35/191 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- CATSPER1 | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 78/224 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- CCNDBP1 | c.710A>C p.D237A | Missense Mutation (SNP) | VAF 83/199 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- CCNT2 | c.281A>T p.E94V | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CDYL2 | c.140A>T p.H47L | Missense Mutation (SNP) | VAF 87/252 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- CEACAM1 | c.605_609del p.L202Qfs*6 | Frame Shift Del (DEL) | VAF 142/422 reads (34%) | called by mutect2, pindel, varscan2
- CEACAM19 | c.460A>G p.T154A | Missense Mutation (SNP) | VAF 68/199 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEL | c.1295dup p.S433Efs*29 (on ENST00000673714; = p.S430Efs*29 on NM_001807.6) | Frame Shift Ins (INS) | VAF 30/236 reads (13%) | called by mutect2, pindel, varscan2
- CEP135 | c.3247C>T p.R1083* | Nonsense Mutation (SNP) | VAF 34/102 reads (33%) | called by muse, mutect2, varscan2
- CHIT1 | c.536T>C p.L179P | Missense Mutation (SNP) | VAF 178/953 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CKAP2 | c.234+1G>A p.X78_splice (on ENST00000378037 / NM_001098525.2; = p.X77_splice on NM_018204.5) | Splice Site (SNP) | VAF 8/27 reads (30%) | called by muse, mutect2, varscan2
- CMIP | c.805C>T p.R269* (on ENST00000537098 / NM_198390.2; = p.R175* on NM_030629.3) | Nonsense Mutation (SNP) | VAF 58/186 reads (31%) | called by muse, mutect2, varscan2
- CNOT1 | c.6575T>G p.F2192C | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2
- CNTNAP4 | c.927+2T>C p.X309_splice | Splice Site (SNP) | VAF 18/174 reads (10%) | called by muse, mutect2
- COCH | c.1267T>C p.C423R (on ENST00000216361 / NM_001347720.1; = p.C358R on NM_004086.3) | Missense Mutation (SNP) | VAF 87/207 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL11A2 | c.1292dup p.G432Wfs*31 (on ENST00000341947 / NM_080680.3; = p.G325Wfs*31 on NM_080679.2) | Frame Shift Ins (INS) | VAF 62/214 reads (29%) | called by mutect2, pindel, varscan2
- COL20A1 | c.3239dup p.G1081Rfs*84 | Frame Shift Ins (INS) | VAF 10/94 reads (11%) | called by mutect2, pindel
- COL2A1 | c.2399A>G p.N800S | Missense Mutation (SNP) | VAF 121/338 reads (36%) | SIFT tolerated (0.84); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- CRHR2 | c.73G>T p.D25Y | Missense Mutation (SNP) | VAF 101/210 reads (48%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- CSTF2T | c.1427A>G p.Q476R | Missense Mutation (SNP) | VAF 77/243 reads (32%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- CWF19L2 | c.1398del p.E467Nfs*22 | Frame Shift Del (DEL) | VAF 21/66 reads (32%) | called by mutect2, pindel, varscan2
- DAGLA | c.343G>A p.G115S | Missense Mutation (SNP) | VAF 18/311 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2
- DELE1 | c.878C>A p.T293N | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DHX40 | c.2066A>G p.Y689C | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- DHX8 | c.2098T>A p.L700M | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DISP3 | c.1008del p.S337Afs*4 | Frame Shift Del (DEL) | VAF 61/221 reads (28%) | called by pindel, varscan2
- DLEU7 | c.212del p.G71Afs*20 | Frame Shift Del (DEL) | VAF 8/19 reads (42%) | called by mutect2, pindel, varscan2
- DLGAP2 | c.2324C>T p.A775V | Missense Mutation (SNP) | VAF 58/119 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DMTF1 | c.1352C>T p.T451I | Missense Mutation (SNP) | VAF 73/215 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DNAH1 | c.11242C>T p.H3748Y | Missense Mutation (SNP) | VAF 60/139 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- DOCK2 | c.144C>A p.Y48* | Nonsense Mutation (SNP) | VAF 29/106 reads (27%) | called by muse, mutect2, varscan2
- EFCAB2 | c.737G>T p.G246V (on ENST00000366522; = p.G110V on NM_032328.3) | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EHF | c.712A>G p.R238G | Missense Mutation (SNP) | VAF 51/160 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ELF1 | c.906G>T p.E302D | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- EP400 | c.4593G>T p.Q1531H | Missense Mutation (SNP) | VAF 49/278 reads (18%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- EPS8L1 | c.874C>T p.R292C (on ENST00000201647 / NM_133180.3; = p.R165C on NM_017729.3) | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- EPX | c.2069G>A p.R690K | Missense Mutation (SNP) | VAF 79/204 reads (39%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAT2 | c.6702G>C p.E2234D | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FBN2 | c.7240G>T p.G2414C | Missense Mutation (SNP) | VAF 199/496 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- FBXW7 | c.664_667delinsAG p.R223Pfs*32 (on ENST00000281708 / NM_001349798.2; = p.R143Pfs*32 on NM_018315.5) | Frame Shift Del (DEL) | VAF 52/198 reads (26%) | called by pindel, varscan2*
- FMNL1 | c.240dup p.A81Rfs*23 | Frame Shift Ins (INS) | VAF 71/243 reads (29%) | called by mutect2, pindel, varscan2
- FOXE1 | c.1073A>G p.H358R | Missense Mutation (SNP) | VAF 26/698 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.056); called by muse, mutect2
- FOXO3 | c.212del p.G71Dfs*49 | Frame Shift Del (DEL) | VAF 59/208 reads (28%) | called by mutect2, pindel, varscan2
- FOXR2 | c.725A>G p.Y242C | Missense Mutation (SNP) | VAF 77/224 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- FRA10AC1 | c.899A>T p.K300I | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FZD4 | c.41C>A p.P14H | Missense Mutation (SNP) | VAF 51/103 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GABRB2 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 81/229 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GALR1 | c.57del p.A20Pfs*23 | Frame Shift Del (DEL) | VAF 50/176 reads (28%) | called by mutect2, pindel, varscan2
- GNA15 | c.377C>T p.T126M | Missense Mutation (SNP) | VAF 56/197 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GNL1 | c.791C>A p.P264Q | Missense Mutation (SNP) | VAF 70/205 reads (34%) | SIFT tolerated (0.55); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GOLM2 | c.647del p.N216Ifs*5 | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | called by mutect2, pindel, varscan2
- GPAM | c.1961G>A p.G654D | Missense Mutation (SNP) | VAF 50/192 reads (26%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPR75 | c.719del p.P240Lfs*2 | Frame Shift Del (DEL) | VAF 52/173 reads (30%) | called by mutect2, pindel, varscan2
- GPR82 | c.817dup p.Y273Lfs*8 | Frame Shift Ins (INS) | VAF 21/55 reads (38%) | called by mutect2, pindel, varscan2
- GSTA3 | c.107G>C p.G36A | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- GSTM3 | c.576del p.F192Lfs*63 | Frame Shift Del (DEL) | VAF 66/199 reads (33%) | called by mutect2, pindel, varscan2
- HADHA | c.2285A>G p.Y762C | Missense Mutation (SNP) | VAF 140/408 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- HIVEP2 | c.1091_1092del p.T364Sfs*18 | Frame Shift Del (DEL) | VAF 50/152 reads (33%) | called by pindel, varscan2
- HSPB1 | c.32T>C p.L11P | Missense Mutation (SNP) | VAF 222/558 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- ICAM5 | c.1682C>T p.A561V | Missense Mutation (SNP) | VAF 74/192 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- IGDCC4 | c.1296del p.T433Rfs*8 | Frame Shift Del (DEL) | VAF 84/250 reads (34%) | called by mutect2, pindel, varscan2
- IGFBP5 | c.490A>G p.K164E | Missense Mutation (SNP) | VAF 102/258 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- IGSF1 | c.2268del p.K756Nfs*17 | Frame Shift Del (DEL) | VAF 55/152 reads (36%) | called by mutect2, pindel, varscan2
- IGSF9 | c.2420A>G p.Q807R (on ENST00000368094 / NM_001135050.2; = p.Q791R on NM_020789.4) | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2
- IL15RA | c.108del p.M37Cfs*36 | Frame Shift Del (DEL) | VAF 14/106 reads (13%) | called by mutect2, pindel
- ING1 | c.715G>A p.V239M | Missense Mutation (SNP) | VAF 94/250 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- INPPL1 | c.2974del p.V992Sfs*139 | Frame Shift Del (DEL) | VAF 69/205 reads (34%) | called by mutect2, pindel, varscan2
- IQCB1 | c.1330T>C p.W444R | Missense Mutation (SNP) | VAF 38/236 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- IRX3 | c.706del p.E236Rfs*24 | Frame Shift Del (DEL) | VAF 46/142 reads (32%) | called by mutect2, varscan2
- ITGA1 | c.616C>T p.Q206* | Nonsense Mutation (SNP) | VAF 12/29 reads (41%) | called by muse, mutect2, varscan2
- ITPR1 | c.3725del p.L1242Cfs*19 (on ENST00000354582; = p.L1227Cfs*19 on NM_002222.7) | Frame Shift Del (DEL) | VAF 23/70 reads (33%) | called by mutect2, pindel, varscan2
- KANK3 | c.1234G>A p.A412T | Missense Mutation (SNP) | VAF 155/401 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- KAT6B | c.6188_6191del p.K2063Sfs*8 | Frame Shift Del (DEL) | VAF 120/567 reads (21%) | called by mutect2, pindel, varscan2
- KCNA2 | c.1386G>T p.Q462H | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- KCNT1 | c.2836G>A p.A946T (on ENST00000488444; = p.A965T on NM_020822.3) | Missense Mutation (SNP) | VAF 16/321 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.386); called by muse, mutect2
- KCTD13 | c.913G>A p.V305I | Missense Mutation (SNP) | VAF 92/263 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- KIAA0319 | c.2353del p.V785Cfs*36 | Frame Shift Del (DEL) | VAF 90/278 reads (32%) | called by mutect2, pindel, varscan2
- KIAA1614 | c.2360A>C p.E787A | Missense Mutation (SNP) | VAF 55/275 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- KIF5B | c.1985A>G p.E662G | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- KISS1 | c.169A>C p.K57Q | Missense Mutation (SNP) | VAF 182/1035 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- KLHDC8A | c.298T>C p.Y100H | Missense Mutation (SNP) | VAF 55/222 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KMT2B | c.4498-1G>C p.X1500_splice | Splice Site (SNP) | VAF 41/144 reads (28%) | called by muse, mutect2, varscan2
- LAMA1 | c.9121A>G p.R3041G | Missense Mutation (SNP) | VAF 117/273 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- LAMB3 | c.1970C>A p.S657Y | Missense Mutation (SNP) | VAF 139/836 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- LARP1 | c.911del p.P304Qfs*22 (on ENST00000518297 / NM_033551.3; = p.P227Qfs*22 on NM_015315.5 and 6 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 93/252 reads (37%) | called by mutect2, pindel, varscan2
- LHX3 | c.598G>A p.V200M (on ENST00000371748 / NM_178138.6; = p.V205M on NM_014564.5) | Missense Mutation (SNP) | VAF 82/196 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- LINGO4 | c.1578del p.L527Wfs*21 | Frame Shift Del (DEL) | VAF 55/304 reads (18%) | called by mutect2, pindel, varscan2
- LMTK3 | c.4283del p.P1428Rfs*56 | Frame Shift Del (DEL) | VAF 6/12 reads (50%) | called by mutect2, varscan2
- LMX1A | c.703A>G p.S235G | Missense Mutation (SNP) | VAF 16/231 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2
- LMX1A | c.104G>A p.C35Y | Missense Mutation (SNP) | VAF 98/371 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRP1 | c.9625C>T p.R3209C | Missense Mutation (SNP) | VAF 112/291 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRRC31 | c.211A>G p.S71G | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRC41 | c.572T>C p.L191P | Missense Mutation (SNP) | VAF 71/157 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRRC7 | c.3192del p.V1065Sfs*16 (on ENST00000651989 / NM_001370785.2; = p.V1032Sfs*16 on NM_001330635.3 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 67/190 reads (35%) | called by mutect2, pindel, varscan2
- MAGI3 | c.1676C>T p.A559V | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT tolerated (0.68); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MANEAL | c.868dup p.H290Pfs*31 (on ENST00000373045 / NM_001113482.1; = p.H68Pfs*31 on NM_152496.2) | Frame Shift Ins (INS) | VAF 112/362 reads (31%) | called by mutect2, pindel, varscan2
- MARK3 | c.529C>T p.R177* | Nonsense Mutation (SNP) | VAF 5/21 reads (24%) | called by muse, mutect2
- MED12 | c.3836C>T p.A1279V | Missense Mutation (SNP) | VAF 109/339 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MEN1 | c.881T>A p.L294Q | Missense Mutation (SNP) | VAF 233/576 reads (40%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- MIPEP | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MRPL27 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 80/196 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MXRA8 | c.900_901del p.R301Gfs*85 | Frame Shift Del (DEL) | VAF 22/210 reads (10%) | called by mutect2, pindel, varscan2
- MYO15A | c.2084G>A p.G695D | Missense Mutation (SNP) | VAF 55/156 reads (35%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NDRG1 | c.227T>C p.L76P | Missense Mutation (SNP) | VAF 73/214 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NKAPD1 | c.479del p.K160Sfs*20 (on ENST00000280352 / NM_001082970.2; = p.K161Sfs*20 on NM_018195.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 26/78 reads (33%) | called by mutect2, varscan2
- NLRP6 | c.2254del p.L752* | Frame Shift Del (DEL) | VAF 85/315 reads (27%) | called by mutect2, pindel, varscan2
- NRAP | c.1633-2A>C p.X545_splice (on ENST00000359988 / NM_001322945.2; = p.X510_splice on NM_006175.4) | Splice Site (SNP) | VAF 45/158 reads (28%) | called by muse, mutect2, varscan2
- NRDE2 | c.3257G>A p.S1086N | Missense Mutation (SNP) | VAF 7/182 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, mutect2
- NYNRIN | c.5194C>A p.L1732M | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- OBSCN | c.6980A>G p.Q2327R | Missense Mutation (SNP) | VAF 162/708 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- OCIAD2 | c.339del p.F113Lfs*27 | Frame Shift Del (DEL) | VAF 39/111 reads (35%) | called by mutect2, pindel, varscan2
- OR4D11 | c.786C>A p.F262L | Missense Mutation (SNP) | VAF 77/253 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- ORC1 | c.107T>C p.V36A | Missense Mutation (SNP) | VAF 49/162 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- OSGEP | c.855del p.F285Lfs*14 | Frame Shift Del (DEL) | VAF 42/142 reads (30%) | called by mutect2, pindel, varscan2
- PCDHB8 | c.1924G>T p.V642L | Missense Mutation (SNP) | VAF 57/636 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); called by muse, mutect2
- PES1 | c.845G>A p.S282N | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- PIK3R1 | c.1719_1722del p.K575Rfs*6 (on ENST00000521381 / NM_181523.3; = p.K305Rfs*6 on NM_181504.4) | Frame Shift Del (DEL) | VAF 21/54 reads (39%) | called by mutect2, pindel, varscan2
- PKP2 | c.752G>C p.S251T | Missense Mutation (SNP) | VAF 155/405 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- PLEKHH3 | c.1589dup p.P531Tfs*114 | Frame Shift Ins (INS) | VAF 19/57 reads (33%) | called by mutect2, pindel, varscan2
- PLEKHM3 | c.1868C>T p.A623V | Missense Mutation (SNP) | VAF 79/227 reads (35%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PLEKHM3 | c.1397A>T p.Q466L | Missense Mutation (SNP) | VAF 51/160 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- POLK | c.1501C>T p.P501S | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- POSTN | c.2126C>A p.P709H | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- POU3F3 | c.1205C>T p.A402V | Missense Mutation (SNP) | VAF 163/415 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- PPP2R5E | c.1304G>A p.R435H | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); called by muse, varscan2
- PPP4R3A | c.373A>G p.M125V | Missense Mutation (SNP) | VAF 49/95 reads (52%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PPP5C | c.46del p.R16Gfs*10 | Frame Shift Del (DEL) | VAF 81/249 reads (33%) | called by mutect2, pindel, varscan2
- PRSS56 | c.380A>G p.Q127R | Missense Mutation (SNP) | VAF 100/266 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PSMB10 | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 82/213 reads (38%) | SIFT tolerated (0.86); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PTPN1 | c.1130del p.G377Efs*27 | Frame Shift Del (DEL) | VAF 37/98 reads (38%) | called by mutect2, pindel, varscan2
- PTPN13 | c.1505G>A p.S502N | Missense Mutation (SNP) | VAF 84/251 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PTPRQ | c.1045G>T p.G349* (on ENST00000616559; = p.G307* on NM_001145026.2) | Nonsense Mutation (SNP) | VAF 23/65 reads (35%) | called by muse, mutect2, varscan2
- R3HCC1L | c.1430del p.K477Rfs*18 | Frame Shift Del (DEL) | VAF 30/107 reads (28%) | called by mutect2, pindel, varscan2
- RAB30 | c.452C>T p.T151I | Missense Mutation (SNP) | VAF 30/215 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RASSF8 | c.1073C>T p.T358I | Missense Mutation (SNP) | VAF 60/205 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- RB1 | c.1212del p.F404Lfs*6 | Frame Shift Del (DEL) | VAF 14/54 reads (26%) | called by mutect2, pindel, varscan2
- RET | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 175/705 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- RET | c.626-1G>T p.X209_splice | Splice Site (SNP) | VAF 123/480 reads (26%) | called by muse, mutect2, varscan2
- REV3L | c.1362T>A p.N454K | Missense Mutation (SNP) | VAF 46/148 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- RFPL4AL1 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- RFX1 | c.2600G>A p.R867H | Missense Mutation (SNP) | VAF 92/232 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RNF186 | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 137/345 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RNF31 | c.1371del p.K458Sfs*34 | Frame Shift Del (DEL) | VAF 25/69 reads (36%) | called by mutect2, pindel
- SCAF4 | c.2156del p.P719Lfs*29 | Frame Shift Del (DEL) | VAF 45/153 reads (29%) | called by mutect2, pindel, varscan2
- SCG3 | c.215_217del p.V72del | In Frame Del (DEL) | VAF 17/46 reads (37%) | called by pindel, varscan2
- SCN4A | c.4933G>A p.D1645N | Missense Mutation (SNP) | VAF 87/240 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.592); called by muse, mutect2, varscan2
- SCO2 | c.686A>G p.Y229C | Missense Mutation (SNP) | VAF 261/660 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SERPINA7 | c.107dup p.N36Kfs*11 | Frame Shift Ins (INS) | VAF 27/71 reads (38%) | called by mutect2, pindel, varscan2
- SHISA6 | c.577G>A p.V193I | Missense Mutation (SNP) | VAF 294/740 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- SHROOM4 | c.3941del p.K1314Rfs*23 | Frame Shift Del (DEL) | VAF 36/96 reads (38%) | called by mutect2, varscan2
- SLC25A23 | c.1111T>A p.S371T | Missense Mutation (SNP) | VAF 43/152 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SLC30A7 | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT tolerated (0.72); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- SLC39A10 | c.1040A>T p.Y347F | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC4A8 | c.2108dup p.T704Hfs*13 | Frame Shift Ins (INS) | VAF 56/189 reads (30%) | called by mutect2, pindel, varscan2
- SLC8A2 | c.107G>T p.S36I | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.276); called by muse, varscan2
- SLITRK1 | c.347A>T p.N116I | Missense Mutation (SNP) | VAF 98/256 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLMAP | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLX4 | c.1972C>T p.P658S | Missense Mutation (SNP) | VAF 248/607 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.219); called by muse, mutect2
- SMC4 | c.1699C>T p.Q567* | Nonsense Mutation (SNP) | VAF 15/33 reads (45%) | called by muse, varscan2
- SNRNP70 | c.986_988del p.D329del | In Frame Del (DEL) | VAF 39/125 reads (31%) | called by pindel, varscan2
- SNTB1 | c.731T>C p.I244T | Missense Mutation (SNP) | VAF 71/190 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- SOCS7 | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 99/286 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, varscan2
- SRGAP2 | c.2243T>A p.F748Y (on ENST00000624873 / NM_001170637.4; = p.F749Y on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/236 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ST6GALNAC4 | c.315G>T p.Q105H | Missense Mutation (SNP) | VAF 95/277 reads (34%) | PolyPhen benign (0.019); called by muse, mutect2, varscan2
- SYN1 | c.1750G>A p.G584R | Missense Mutation (SNP) | VAF 61/139 reads (44%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TBC1D10B | c.1882C>A p.L628M | Missense Mutation (SNP) | VAF 90/242 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TBX4 | c.143dup p.P50Tfs*24 | Frame Shift Ins (INS) | VAF 10/85 reads (12%) | called by pindel, varscan2
- TBX4 | c.1111_1112del p.P371Sfs*14 | Frame Shift Del (DEL) | VAF 31/99 reads (31%) | called by mutect2, pindel, varscan2
- TCEA3 | c.495_496insA p.L166Ifs*39 | Frame Shift Ins (INS) | VAF 79/238 reads (33%) | called by mutect2, pindel, varscan2
- TEK | c.565T>C p.Y189H | Missense Mutation (SNP) | VAF 140/394 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- TIE1 | c.2812G>A p.D938N | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- TIGD2 | c.295G>T p.G99* | Nonsense Mutation (SNP) | VAF 34/112 reads (30%) | called by muse, mutect2, varscan2
- TIMELESS | c.2631G>T p.K877N | Missense Mutation (SNP) | VAF 55/154 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.704); called by muse, mutect2, varscan2
- TLK1 | c.968A>G p.Q323R | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TMEM151B | c.899C>T p.S300L | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT tolerated (0.65); PolyPhen benign (0.094); called by muse, mutect2
- TNFSF12-TNFSF13 | c.43del p.E15Sfs*57 | Frame Shift Del (DEL) | VAF 27/80 reads (34%) | called by mutect2, pindel, varscan2
- TPR | c.2687del p.N896Mfs*9 | Frame Shift Del (DEL) | VAF 19/131 reads (15%) | called by mutect2, pindel, varscan2
- TRAV1-2 | c.298T>G p.S100A | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.702); called by muse, mutect2
- TRAV3 | c.277T>G p.F93V | Missense Mutation (SNP) | VAF 58/132 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- TRBV23-1 | c.138del p.G47Dfs*19 | Frame Shift Del (DEL) | VAF 31/93 reads (33%) | called by mutect2, pindel, varscan2
- TRPV4 | c.2554del p.R852Afs*35 | Frame Shift Del (DEL) | VAF 47/281 reads (17%) | called by mutect2, pindel, varscan2
- TTC39C | c.422A>T p.Y141F (on ENST00000317571 / NM_001135993.2; = p.Y80F on NM_153211.4) | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated (0.69); PolyPhen benign (0.047); called by muse, varscan2
- TTLL5 | c.1559_1561del p.A520del | In Frame Del (DEL) | VAF 27/73 reads (37%) | called by pindel, varscan2
- TTN | c.78124A>G p.K26042E (on ENST00000591111; = p.K18618E on NM_003319.4) | Missense Mutation (SNP) | VAF 34/82 reads (41%) | PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- UHMK1 | c.394A>G p.M132V | Missense Mutation (SNP) | VAF 26/564 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.028); called by muse, mutect2
- UNCX | c.1235C>T p.A412V | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- UQCRC2 | c.1003C>T p.L335F | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- USP16 | c.868G>C p.V290L | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- USP35 | c.1502dup p.E502Rfs*103 | Frame Shift Ins (INS) | VAF 44/167 reads (26%) | called by mutect2, pindel, varscan2
- USP39 | c.582G>T p.K194N | Missense Mutation (SNP) | VAF 59/159 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- USP9X | c.7147del p.R2383Efs*6 | Frame Shift Del (DEL) | VAF 23/91 reads (25%) | called by mutect2, pindel, varscan2
- USPL1 | c.2588_2592del p.L863Pfs*14 | Frame Shift Del (DEL) | VAF 44/138 reads (32%) | called by pindel, varscan2
- VASH2 | c.233dup p.E79Rfs*46 (on ENST00000517399 / NM_001301056.2; = p.E79Rfs*54 on NM_024749.5) | Frame Shift Ins (INS) | VAF 70/388 reads (18%) | called by mutect2, pindel, varscan2
- WDR72 | c.278A>G p.N93S | Missense Mutation (SNP) | VAF 79/239 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- WWC3 | c.655G>T p.E219* | Nonsense Mutation (SNP) | VAF 55/165 reads (33%) | called by muse, mutect2, varscan2
- ZBED1 | c.1936T>C p.F646L | Missense Mutation (SNP) | VAF 81/237 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- ZBTB11 | c.2626C>T p.H876Y | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZC2HC1A | c.698A>G p.H233R | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZCCHC3 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- ZNF296 | c.264G>T p.W88C | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF469 | c.5619del p.I1874Yfs*24 (on ENST00000437464; = p.I1902Yfs*24 on NM_001367624.2) | Frame Shift Del (DEL) | VAF 157/433 reads (36%) | called by mutect2, pindel, varscan2
- ZNF536 | c.3644C>T p.S1215F | Missense Mutation (SNP) | VAF 91/221 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ZNF672 | c.1301C>T p.T434I | Missense Mutation (SNP) | VAF 69/287 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF792 | c.1303G>A p.A435T | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNFX1 | c.622C>G p.L208V | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- ABCA2 | c.1239T>C p.A413= (on ENST00000614293; = p.A383= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 52/129 reads (40%) | catalogued as rs890991270; called by muse, mutect2, varscan2
- ADAP1 | c.291G>A p.T97= | Silent (SNP) | VAF 28/104 reads (27%) | catalogued as rs886144845; called by muse, mutect2, varscan2
- ADORA3 | c.528C>T p.Y176= | Silent (SNP) | VAF 60/141 reads (43%) | catalogued as rs754687706; called by muse, mutect2, varscan2
- ADRB1 | c.177G>A p.A59= | Silent (SNP) | VAF 67/214 reads (31%) | catalogued as rs751191292; called by muse, mutect2, varscan2
- AFF4 | c.3379C>T p.L1127= | Silent (SNP) | VAF 48/137 reads (35%) | called by muse, mutect2, varscan2
- AGT | c.1027C>T p.L343= | Silent (SNP) | VAF 122/763 reads (16%) | catalogued as rs1263387254; called by muse, mutect2, varscan2
- AKNA | c.4062C>T p.A1354= | Silent (SNP) | VAF 33/269 reads (12%) | catalogued as rs558717087; called by muse, mutect2, varscan2
- APOA2 | c.177C>T p.A59= | Silent (SNP) | VAF 138/718 reads (19%) | catalogued as rs370208442; called by muse, mutect2, varscan2
- AQP5 | c.291C>T p.G97= | Silent (SNP) | VAF 116/297 reads (39%) | called by muse, mutect2, varscan2
- ARAP3 | c.1668A>G p.V556= | Silent (SNP) | VAF 38/211 reads (18%) | called by muse, mutect2, varscan2
- ARHGEF17 | c.1047G>A p.P349= | Silent (SNP) | VAF 12/160 reads (8%) | called by muse, mutect2
- ASB4 | c.814C>T p.L272= | Silent (SNP) | VAF 102/231 reads (44%) | called by muse, mutect2, varscan2
- BAHD1 | c.1560T>C p.H520= | Silent (SNP) | VAF 65/214 reads (30%) | called by muse, mutect2, varscan2
- BMP2K | c.2472T>C p.S824= | Silent (SNP) | VAF 30/76 reads (39%) | called by muse, mutect2, varscan2
- BMP4 | c.855C>A p.T285= | Silent (SNP) | VAF 46/141 reads (33%) | catalogued as rs1319753678; called by muse, mutect2, varscan2
- BRAP | c.186G>A p.Q62= | Silent (SNP) | VAF 35/91 reads (38%) | catalogued as rs1398741063; called by muse, mutect2, varscan2
- C12orf56 | c.1578T>C p.P526= (on ENST00000543942 / NM_001170633.2; = p.P366= on NM_001099676.3) | Silent (SNP) | VAF 26/76 reads (34%) | called by muse, mutect2, varscan2
- C20orf194 | c.3510T>C p.H1170= | Silent (SNP) | VAF 50/141 reads (35%) | called by muse, mutect2, varscan2
- C8B | c.660G>A p.T220= | Silent (SNP) | VAF 133/344 reads (39%) | catalogued as rs370360066; called by muse, mutect2, varscan2
- CAMK2D | c.477C>G p.G159= | Silent (SNP) | VAF 77/177 reads (44%) | called by muse, mutect2, varscan2
- CD9 | c.630C>A p.G210= | Silent (SNP) | VAF 32/95 reads (34%) | called by muse, mutect2, varscan2
- CDCA5 | c.396C>T p.D132= | Silent (SNP) | VAF 29/67 reads (43%) | catalogued as rs765815329, COSV51870761; called by muse, mutect2, varscan2
- CDX4 | c.399C>T p.G133= | Silent (SNP) | VAF 83/192 reads (43%) | called by muse, mutect2, varscan2
- CEBPB | c.603G>A p.A201= | Silent (SNP) | VAF 97/193 reads (50%) | catalogued as rs997116351; called by muse, mutect2, varscan2
- CEP126 | c.357G>A p.Q119= | Silent (SNP) | VAF 38/130 reads (29%) | called by muse, mutect2, varscan2
- COL23A1 | c.402C>T p.D134= | Silent (SNP) | VAF 19/53 reads (36%) | called by muse, mutect2, varscan2
- COL8A2 | c.1296G>A p.T432= | Silent (SNP) | VAF 119/296 reads (40%) | catalogued as rs762703964; called by muse, mutect2, varscan2
- COL9A2 | c.1350C>T p.P450= | Silent (SNP) | VAF 146/370 reads (39%) | catalogued as COSV65622262; called by muse, mutect2, varscan2
- CSRNP1 | c.1563A>G p.T521= | Silent (SNP) | VAF 45/207 reads (22%) | called by muse, mutect2, varscan2
- CUEDC1 | c.468C>T p.I156= | Silent (SNP) | VAF 21/43 reads (49%) | catalogued as rs111753270; called by muse, mutect2, varscan2
- DLL4 | c.999T>C p.C333= | Silent (SNP) | VAF 102/226 reads (45%) | catalogued as rs773508830; called by muse, mutect2, varscan2
- DMXL2 | c.5664T>C p.T1888= | Silent (SNP) | VAF 9/21 reads (43%) | called by muse, mutect2, varscan2
- DNM3 | c.2013C>T p.S671= (on ENST00000355305 / NM_001350206.2; = p.S665= on NM_015569.5) | Silent (SNP) | VAF 38/208 reads (18%) | called by muse, varscan2
- E2F8 | c.907T>C p.L303= | Silent (SNP) | VAF 35/72 reads (49%) | called by muse, mutect2, varscan2
- EPS8L3 | c.846A>G p.A282= | Silent (SNP) | VAF 87/257 reads (34%) | called by muse, mutect2, varscan2
- EVX2 | c.1257T>C p.G419= | Silent (SNP) | VAF 20/87 reads (23%) | catalogued as rs1197853839; called by muse, mutect2, varscan2
- EXOC2 | c.2151T>C p.N717= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as rs1462808882; called by muse, mutect2
- F11R | c.450G>A p.V150= | Silent (SNP) | VAF 71/463 reads (15%) | called by muse, mutect2, varscan2
- F13A1 | c.2148A>G p.R716= | Silent (SNP) | VAF 151/487 reads (31%) | catalogued as COSV53555828; called by muse, mutect2, varscan2
- FAAP100 | c.2235C>T p.V745= | Silent (SNP) | VAF 72/225 reads (32%) | catalogued as rs768330250; called by muse, mutect2, varscan2
- FAM47A | c.2235C>T p.S745= | Silent (SNP) | VAF 29/72 reads (40%) | catalogued as COSV60494333, COSV60495887; called by muse, mutect2, varscan2
- FBN1 | c.4539C>T p.C1513= | Silent (SNP) | VAF 105/333 reads (32%) | catalogued as CM065178; called by muse, mutect2, varscan2
- FIZ1 | c.669C>T p.T223= | Silent (SNP) | VAF 50/146 reads (34%) | catalogued as COSV55608000; called by muse, mutect2, varscan2
- FRMD1 | c.1248C>T p.D416= | Silent (SNP) | VAF 88/239 reads (37%) | catalogued as rs755246476, COSV51959768; called by muse, mutect2, varscan2
- FTMT | c.177C>A p.T59= | Silent (SNP) | VAF 54/114 reads (47%) | called by muse, mutect2, varscan2
- GALNT7 | c.1782A>G p.K594= | Silent (SNP) | VAF 13/114 reads (11%) | called by muse, mutect2, varscan2
- GPATCH4 | c.714T>C p.A238= | Silent (SNP) | VAF 74/365 reads (20%) | called by muse, mutect2, varscan2
- GPR25 | c.726G>A p.S242= | Silent (SNP) | VAF 106/494 reads (21%) | catalogued as COSV58498341, COSV58499242; called by muse, varscan2
- H4C1 | c.96G>A p.K32= | Silent (SNP) | VAF 95/261 reads (36%) | called by muse, mutect2, varscan2
- HCAR1 | c.657C>A p.T219= | Silent (SNP) | VAF 104/264 reads (39%) | catalogued as rs767155988; called by muse, mutect2, varscan2
- HDAC5 | c.2208G>A p.T736= | Silent (SNP) | VAF 49/116 reads (42%) | catalogued as rs372547487, COSV56820860; called by muse, mutect2, varscan2
- HECTD4 | c.10530G>A p.L3510= | Silent (SNP) | VAF 58/143 reads (41%) | catalogued as rs1202396543; called by muse, mutect2, varscan2
- HIRIP3 | c.873C>T p.S291= | Silent (SNP) | VAF 13/107 reads (12%) | catalogued as rs765119373, COSV54231273; called by muse, mutect2
- HMX3 | c.132G>A p.P44= | Silent (SNP) | VAF 24/102 reads (24%) | called by muse, varscan2
- HTR1F | c.153C>T p.T51= | Silent (SNP) | VAF 95/270 reads (35%) | catalogued as COSV60390448; called by muse, mutect2, varscan2
- IGF1R | c.2445C>T p.C815= | Silent (SNP) | VAF 73/212 reads (34%) | called by muse, mutect2, varscan2
- IGFBP5 | c.751C>T p.L251= | Silent (SNP) | VAF 76/216 reads (35%) | called by muse, varscan2
- INO80D | c.2325T>G p.L775= | Silent (SNP) | VAF 95/266 reads (36%) | catalogued as rs530833163; called by muse, mutect2, varscan2
- ITGA2 | c.531T>G p.V177= | Silent (SNP) | VAF 52/185 reads (28%) | called by muse, mutect2, varscan2
- KBTBD11 | c.1644G>A p.T548= | Silent (SNP) | VAF 73/145 reads (50%) | called by muse, mutect2, varscan2
- KCND2 | c.114C>A p.T38= | Silent (SNP) | VAF 67/151 reads (44%) | called by muse, mutect2, varscan2
- KIF21B | c.4521C>T p.I1507= (on ENST00000422435 / NM_001252100.2; = p.I1494= on NM_017596.4) | Silent (SNP) | VAF 66/431 reads (15%) | catalogued as rs267598287; called by muse, mutect2, varscan2
- KIF26B | c.2340C>T p.A780= | Silent (SNP) | VAF 68/371 reads (18%) | catalogued as rs532973058, COSV63644934; called by muse, mutect2, varscan2
- KLHL14 | c.1872A>C p.V624= | Silent (SNP) | VAF 24/71 reads (34%) | catalogued as COSV63831821; called by muse, mutect2
- KLHL21 | c.1560C>T p.Y520= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as rs377290952; called by muse, mutect2, varscan2
- KLHL34 | c.693C>T p.D231= | Silent (SNP) | VAF 64/147 reads (44%) | catalogued as rs981857318, COSV65278721; called by muse, mutect2, varscan2
- KSR2 | c.1083C>A p.S361= | Silent (SNP) | VAF 17/162 reads (10%) | catalogued as COSV56685326; called by muse, mutect2
- LAMC2 | c.508C>A p.R170= | Silent (SNP) | VAF 59/321 reads (18%) | called by muse, mutect2, varscan2
- LRRC17 | c.880C>T p.L294= | Silent (SNP) | VAF 14/45 reads (31%) | called by muse, mutect2, varscan2
- LYST | c.5112A>G p.P1704= | Silent (SNP) | VAF 7/167 reads (4%) | called by muse, mutect2
- MAPK4 | c.1500G>A p.T500= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs1467037547; called by muse, mutect2
- MAS1L | c.570T>C p.S190= | Silent (SNP) | VAF 17/125 reads (14%) | catalogued as COSV65808475; called by muse, mutect2, varscan2
- MASTL | c.2397A>G p.E799= (on ENST00000375940 / NM_001372029.1; = p.E798= on NM_032844.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 27/167 reads (16%) | catalogued as COSV60910449; called by muse, mutect2, varscan2
- ME1 | c.540C>T p.C180= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as rs754174776, COSV100866438; called by muse, mutect2, varscan2
- MRC1 | c.1908G>A p.P636= | Silent (SNP) | VAF 144/600 reads (24%) | catalogued as rs781948465; called by muse, mutect2, varscan2
- MS4A15 | c.297C>T p.H99= (on ENST00000405633 / NM_001098835.2; = p.H6= on NM_152717.3) | Silent (SNP) | VAF 51/137 reads (37%) | called by muse, mutect2, varscan2
- MTUS1 | c.1671G>A p.P557= | Silent (SNP) | VAF 78/234 reads (33%) | catalogued as rs745717647; called by muse, mutect2, varscan2
- NAIF1 | c.168C>T p.N56= | Silent (SNP) | VAF 36/247 reads (15%) | catalogued as rs1340661373; called by muse, mutect2, varscan2
- NCOR2 | c.4638C>T p.H1546= | Silent (SNP) | VAF 25/55 reads (45%) | catalogued as rs1469646094; called by muse, mutect2, varscan2
- NFAT5 | c.1680T>C p.S560= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as rs1031086836; called by muse, mutect2, varscan2
- NFX1 | c.285G>A p.S95= | Silent (SNP) | VAF 41/153 reads (27%) | catalogued as rs777875408, COSV100582094; called by muse, mutect2, varscan2
- NOS1 | c.18C>T p.F6= | Silent (SNP) | VAF 31/80 reads (39%) | catalogued as rs199921187; called by mutect2, varscan2
- NOTCH3 | c.5451A>C p.S1817= | Silent (SNP) | VAF 116/282 reads (41%) | catalogued as COSV54625230; called by muse, mutect2, varscan2
- NPIPB11 | c.3087T>A p.R1029= | Silent (SNP) | VAF 184/526 reads (35%) | called by muse, mutect2, varscan2
- NR4A2 | c.1119C>T p.V373= | Silent (SNP) | VAF 217/452 reads (48%) | catalogued as COSV59894390; called by muse, mutect2, varscan2
- OXR1 | c.1767T>C p.H589= (on ENST00000442977 / NM_001198532.1; = p.H588= on NM_018002.3) | Silent (SNP) | VAF 10/33 reads (30%) | called by muse, mutect2, varscan2
- PCDH17 | c.1518C>T p.T506= | Silent (SNP) | VAF 133/319 reads (42%) | called by muse, mutect2, varscan2
- PCDHA4 | c.1902G>A p.T634= | Silent (SNP) | VAF 212/572 reads (37%) | catalogued as COSV100793181, COSV100793358; called by muse, mutect2, varscan2
- PLXNA1 | c.2322C>T p.Y774= | Silent (SNP) | VAF 101/271 reads (37%) | catalogued as rs147176760; called by muse, mutect2, varscan2
- PNPT1 | c.1875C>T p.G625= | Silent (SNP) | VAF 38/99 reads (38%) | called by muse, varscan2
- POU4F1 | c.777C>T p.C259= | Silent (SNP) | VAF 89/272 reads (33%) | called by muse, mutect2, varscan2
- PPP1R12B | c.960G>A p.E320= | Silent (SNP) | VAF 22/64 reads (34%) | called by muse, mutect2, varscan2
- PPP1R35 | c.229C>A p.R77= | Silent (SNP) | VAF 49/90 reads (54%) | called by muse, mutect2, varscan2
- RALY | c.468G>A p.R156= (on ENST00000246194 / NM_016732.3; = p.R140= on NM_007367.4) | Silent (SNP) | VAF 91/223 reads (41%) | called by muse, mutect2, varscan2
- RAPGEF6 | c.786C>T p.D262= | Silent (SNP) | VAF 33/95 reads (35%) | catalogued as COSV99725380; called by muse, mutect2, varscan2
- RBBP5 | c.132T>C p.N44= | Silent (SNP) | VAF 84/395 reads (21%) | called by muse, mutect2, varscan2
- RELB | c.1587C>T p.P529= | Silent (SNP) | VAF 48/122 reads (39%) | catalogued as rs770384014, COSV55510863; called by muse, mutect2, varscan2
- REV3L | c.6048C>T p.Y2016= | Silent (SNP) | VAF 33/107 reads (31%) | catalogued as rs753982547, COSV62617280; called by muse, mutect2, varscan2
- RYBP | c.603C>T p.S201= | Silent (SNP) | VAF 141/325 reads (43%) | called by muse, mutect2, varscan2
- SERTAD2 | c.333G>A p.A111= | Silent (SNP) | VAF 31/70 reads (44%) | catalogued as rs779794166, COSV100512224; called by muse, mutect2, varscan2
- SETBP1 | c.1431A>G p.S477= | Silent (SNP) | VAF 176/424 reads (42%) | called by muse, varscan2
- SHF | c.1050T>C p.S350= | Silent (SNP) | VAF 106/285 reads (37%) | catalogued as rs1474701053; called by muse, mutect2, varscan2
- SLC12A1 | c.897T>C p.N299= | Silent (SNP) | VAF 46/111 reads (41%) | called by muse, mutect2, varscan2
- SLC35G3 | c.123G>A p.L41= | Silent (SNP) | VAF 12/356 reads (3%) | called by muse, mutect2
- SLC4A7 | c.3234G>A p.P1078= | Silent (SNP) | VAF 46/145 reads (32%) | catalogued as rs747613260, COSV55403551; called by muse, mutect2, varscan2
- SLC5A9 | c.651G>A p.T217= | Silent (SNP) | VAF 62/192 reads (32%) | catalogued as rs61730938, COSV52581784, COSV99361310; called by muse, mutect2, varscan2
- SMARCC2 | c.1155T>C p.D385= | Silent (SNP) | VAF 55/161 reads (34%) | called by muse, mutect2, varscan2
- SNAP91 | c.1830T>G p.T610= | Silent (SNP) | VAF 32/127 reads (25%) | called by muse, mutect2, varscan2
- SOGA1 | c.4887G>A p.S1629= | Silent (SNP) | VAF 21/182 reads (12%) | catalogued as rs1181936454; called by muse, mutect2, varscan2
- SORBS1 | c.1173A>T p.S391= (on ENST00000361941 / NM_001034954.2; = p.S227= on NM_006434.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/69 reads (41%) | called by muse, mutect2, varscan2
- SORL1 | c.2940G>A p.Q980= | Silent (SNP) | VAF 60/146 reads (41%) | called by muse, mutect2, varscan2
- SPTBN1 | c.2236C>T p.L746= | Silent (SNP) | VAF 11/246 reads (4%) | called by muse, mutect2
- SSTR4 | c.378C>T p.D126= | Silent (SNP) | VAF 37/93 reads (40%) | catalogued as rs770914493, COSV54796826; called by muse, mutect2, varscan2
- TAPBPL | c.685C>T p.L229= | Silent (SNP) | VAF 155/437 reads (35%) | catalogued as rs1161833645; called by muse, mutect2, varscan2
- TARS2 | c.231C>T p.N77= | Silent (SNP) | VAF 46/180 reads (26%) | called by muse, mutect2, varscan2
- TAS2R3 | c.384G>A p.R128= | Silent (SNP) | VAF 37/88 reads (42%) | called by muse, mutect2, varscan2
- TBL1X | c.540C>T p.A180= | Silent (SNP) | VAF 64/216 reads (30%) | catalogued as rs767736403; called by muse, varscan2
- TFCP2L1 | c.972G>A p.S324= | Silent (SNP) | VAF 58/236 reads (25%) | catalogued as rs772260501, COSV55292569; called by muse, mutect2, varscan2
- TFIP11 | c.2115T>C p.N705= | Silent (SNP) | VAF 10/128 reads (8%) | called by muse, mutect2
- TINAGL1 | c.297T>C p.F99= | Silent (SNP) | VAF 17/134 reads (13%) | called by muse, mutect2, varscan2
- TMEM169 | c.387G>A p.L129= | Silent (SNP) | VAF 89/335 reads (27%) | catalogued as rs367789628; called by muse, mutect2, varscan2
- TMEM266 | c.792G>A p.A264= | Silent (SNP) | VAF 64/195 reads (33%) | catalogued as rs1325330594, COSV66381073; called by muse, mutect2, varscan2
- TNKS1BP1 | c.3678C>T p.D1226= | Silent (SNP) | VAF 31/240 reads (13%) | called by muse, mutect2, varscan2
- TNN | c.2721G>A p.P907= | Silent (SNP) | VAF 107/576 reads (19%) | catalogued as rs141014433; called by muse, mutect2, varscan2
- TRAPPC12 | c.762C>T p.P254= | Silent (SNP) | VAF 62/156 reads (40%) | catalogued as rs774631193; called by muse, mutect2, varscan2
- TRIM9 | c.258C>T p.S86= | Silent (SNP) | VAF 15/28 reads (54%) | called by muse, mutect2, varscan2
- TWSG1 | c.141G>A p.R47= | Silent (SNP) | VAF 76/216 reads (35%) | called by muse, mutect2, varscan2
- USH2A | c.8826C>T p.D2942= | Silent (SNP) | VAF 54/271 reads (20%) | catalogued as rs775823422; called by muse, mutect2, varscan2
- WFS1 | c.1728C>T p.G576= | Silent (SNP) | VAF 98/268 reads (37%) | called by muse, mutect2, varscan2
- ZNF251 | c.180G>A p.K60= | Silent (SNP) | VAF 23/61 reads (38%) | catalogued as rs766617370; called by muse, mutect2, varscan2
- ZNF257 | c.1212A>G p.E404= | Silent (SNP) | VAF 38/99 reads (38%) | catalogued as rs775808287; called by muse, mutect2, varscan2
- ZNF544 | c.1680C>T p.N560= | Silent (SNP) | VAF 30/72 reads (42%) | called by muse, mutect2, varscan2
- ZNF546 | c.2148T>C p.T716= | Silent (SNP) | VAF 10/65 reads (15%) | called by muse, mutect2, varscan2
- ZNF556 | c.1092A>G p.Q364= | Silent (SNP) | VAF 69/165 reads (42%) | catalogued as rs1266486918; called by muse, mutect2, varscan2
- ZNF644 | c.1824G>A p.L608= | Silent (SNP) | VAF 33/92 reads (36%) | called by muse, mutect2, varscan2
- ZXDB | c.1122C>T p.P374= | Silent (SNP) | VAF 104/358 reads (29%) | called by muse, mutect2, varscan2
- AC093155.3 | c.767-1049C>T | Intron (SNP) | VAF 87/228 reads (38%) | catalogued as rs961641651; called by muse, mutect2, varscan2
- AC100872.1 | chr8:122670527 del A | 5'Flank (DEL) | VAF 20/56 reads (36%) | catalogued as rs750918355; called by mutect2, varscan2
- AC107023.1 | chr12:40444462 G>A | 5'Flank (SNP) | VAF 46/130 reads (35%) | called by muse, mutect2, varscan2
- ACADVL | c.1182+72del | Intron (DEL) | VAF 37/110 reads (34%) | called by mutect2, pindel, varscan2
- ACP4 | chr19:50798250 G>A | 3'Flank (SNP) | VAF 39/113 reads (35%) | catalogued as rs1021594886; called by muse, mutect2, varscan2
- ADAM22 | c.992+35del | Intron (DEL) | VAF 10/30 reads (33%) | catalogued as rs1345745155; called by mutect2, pindel, varscan2
- AF186192.2 | chr8:144698889 del G | 5'Flank (DEL) | VAF 43/129 reads (33%) | catalogued as rs939045252; called by mutect2, pindel, varscan2
- AFDN | chr6:167976177 ins G | 3'Flank (INS) | VAF 22/85 reads (26%) | catalogued as rs1219378445; called by mutect2, pindel
- AGAP1 | c.163+29686del | Intron (DEL) | VAF 11/29 reads (38%) | called by mutect2, pindel, varscan2
- ALG6 | c.82+30del | Intron (DEL) | VAF 19/64 reads (30%) | catalogued as rs559834759, COSV54763801; called by mutect2, varscan2
- ANXA8 | c.*181C>T | 3'UTR (SNP) | VAF 154/853 reads (18%) | called by muse, mutect2, varscan2
- ARL13B | c.130+613del | Intron (DEL) | VAF 24/81 reads (30%) | called by mutect2, pindel, varscan2
- ARPP21 | c.898-10del | Intron (DEL) | VAF 25/63 reads (40%) | catalogued as rs751740483; called by mutect2, varscan2
- CCDC50 | c.-48G>A | 5'UTR (SNP) | VAF 98/236 reads (42%) | called by muse, mutect2, varscan2
- CDC14B | c.160+668C>T | Intron (SNP) | VAF 119/313 reads (38%) | called by muse, mutect2, varscan2
- CDCA7 | c.*25T>C | 3'UTR (SNP) | VAF 4/74 reads (5%) | called by muse, mutect2
- CDK5RAP3 | chr17:47971080 C>A | 5'Flank (SNP) | VAF 49/154 reads (32%) | called by muse, mutect2, varscan2
- COX17 | c.107+347G>A | Intron (SNP) | VAF 37/113 reads (33%) | catalogued as rs1225020051; called by muse, mutect2, varscan2
- CUL7 | c.-152C>A | 5'UTR (SNP) | VAF 76/191 reads (40%) | called by muse, mutect2, varscan2
- DDX11 | c.638+900G>A | Intron (SNP) | VAF 144/406 reads (35%) | catalogued as rs1215835829; called by muse, mutect2, varscan2
- DHRS9 | c.1del | 5'UTR (DEL) | VAF 10/46 reads (22%) | called by mutect2, pindel
- DMXL2 | c.7923+24A>G | Intron (SNP) | VAF 10/25 reads (40%) | called by muse, mutect2, varscan2
- DOK6 | c.-36C>T | 5'UTR (SNP) | VAF 87/255 reads (34%) | catalogued as rs1218006178, COSV101235037; called by muse, mutect2, varscan2
- EIF2B3 | c.454+858C>T | Intron (SNP) | VAF 6/14 reads (43%) | called by muse, varscan2
- ELOVL5 | c.246+3874G>A | Intron (SNP) | VAF 16/411 reads (4%) | catalogued as rs1343832021; called by muse, mutect2
- EXOC6 | c.458+16del | Intron (DEL) | VAF 17/61 reads (28%) | catalogued as rs758347935; called by mutect2, pindel, varscan2
- FAM181A | c.100-576C>T | Intron (SNP) | VAF 58/160 reads (36%) | called by muse, mutect2, varscan2
- FAM205BP | n.1977G>A | RNA (SNP) | VAF 104/468 reads (22%) | called by mutect2, varscan2
- FAM230J | n.730G>T | RNA (SNP) | VAF 44/234 reads (19%) | called by muse, mutect2, varscan2
- FANCC | c.996+1559dup | Intron (INS) | VAF 76/221 reads (34%) | called by mutect2, varscan2
- FBXO24 | c.39+75T>A | Intron (SNP) | VAF 155/387 reads (40%) | catalogued as rs767611802; called by muse, mutect2, varscan2
- FXR1 | c.51+2875del | Intron (DEL) | VAF 35/114 reads (31%) | catalogued as rs756396894; called by mutect2, varscan2
- GHRHR | c.974+50del | Intron (DEL) | VAF 39/127 reads (31%) | called by mutect2, pindel, varscan2
- GNAS | c.2068+240C>T | Intron (SNP) | VAF 71/214 reads (33%) | catalogued as rs967732544; called by muse, mutect2, varscan2
- GPM6B | c.-11dup | 5'UTR (INS) | VAF 14/54 reads (26%) | called by mutect2, pindel, varscan2
- HAND2 | c.555+16C>T | Intron (SNP) | VAF 100/253 reads (40%) | catalogued as rs779116452, COSV64019028, COSV64019408; called by muse, mutect2, varscan2
- HMGA1 | c.*321del | 3'UTR (DEL) | VAF 54/146 reads (37%) | called by mutect2, pindel, varscan2
- IKBKB | c.*9del | 3'UTR (DEL) | VAF 70/196 reads (36%) | called by mutect2, varscan2
- JAKMIP2 | c.2413-2775T>C | Intron (SNP) | VAF 70/145 reads (48%) | called by muse, mutect2, varscan2
- KCNC3 | c.*1385C>T | 3'UTR (SNP) | VAF 30/73 reads (41%) | called by muse, mutect2, varscan2
- LARS2 | c.*865G>A | 3'UTR (SNP) | VAF 85/244 reads (35%) | catalogued as COSV99648458; called by muse, mutect2, varscan2
- LINC00269 | n.431C>T | RNA (SNP) | VAF 96/225 reads (43%) | catalogued as rs1309911114; called by muse, mutect2, varscan2
- LINC02453 | n.203T>G | RNA (SNP) | VAF 15/54 reads (28%) | called by muse, varscan2
- LIPT2 | chr11:74497761 C>A | 5'Flank (SNP) | VAF 27/81 reads (33%) | called by muse, mutect2, varscan2
- LITAF | c.*816del | 3'UTR (DEL) | VAF 20/62 reads (32%) | catalogued as rs758850868; ClinVar: uncertain significance; called by mutect2, varscan2
- LRATD1 | c.*704del | 3'UTR (DEL) | VAF 95/338 reads (28%) | called by mutect2, pindel, varscan2
- LRRC8D | c.-141C>T | 5'UTR (SNP) | VAF 63/197 reads (32%) | called by muse, mutect2, varscan2
- MAPK9 | c.122+426C>T | Intron (SNP) | VAF 9/184 reads (5%) | called by muse, mutect2
- MIRLET7BHG | n.170G>A | RNA (SNP) | VAF 76/244 reads (31%) | catalogued as rs149867851; called by muse, mutect2, varscan2
- MUCL3 | c.946+868A>G | Intron (SNP) | VAF 52/246 reads (21%) | catalogued as rs1305952989, COSV58516256; called by muse, mutect2, varscan2
- NAV2 | c.268-54564G>T | Intron (SNP) | VAF 92/253 reads (36%) | catalogued as COSV62328604; called by muse, mutect2, varscan2
- NDRG1 | c.-18-521G>A | Intron (SNP) | VAF 40/136 reads (29%) | catalogued as rs1260862917; called by muse, mutect2, varscan2
- NOC2LP2 | n.828G>A | RNA (SNP) | VAF 14/384 reads (4%) | called by muse, mutect2
- NPHP4 | c.2611+609A>T | Intron (SNP) | VAF 8/88 reads (9%) | called by muse, mutect2
- NPM2 | c.-33-18C>T | Intron (SNP) | VAF 56/148 reads (38%) | catalogued as rs367880291; called by muse, mutect2, varscan2
- NRIP3 | c.*612G>A | 3'UTR (SNP) | VAF 17/50 reads (34%) | catalogued as rs1339089593, COSV100487129; called by muse, mutect2, varscan2
- PADI1 | c.*96dup | 3'UTR (INS) | VAF 174/567 reads (31%) | called by mutect2, pindel, varscan2
- PARGP1 | n.1410G>A | RNA (SNP) | VAF 20/120 reads (17%) | called by muse, mutect2, varscan2
- PCSK6 | c.2699+61G>A | Intron (SNP) | VAF 71/189 reads (38%) | called by muse, mutect2, varscan2
- PLSCR3 | c.286+9_286+11del | Intron (DEL) | VAF 152/401 reads (38%) | catalogued as rs1291758147; called by mutect2, pindel, varscan2
- PNPLA6 | c.-21C>A | 5'UTR (SNP) | VAF 47/173 reads (27%) | called by muse, mutect2, varscan2
- PRKCB | c.-5G>A | 5'UTR (SNP) | VAF 92/233 reads (39%) | called by muse, mutect2, varscan2
- RAB18 | c.*3191C>T | 3'UTR (SNP) | VAF 26/243 reads (11%) | called by muse, mutect2, varscan2
- RN7SL106P | chr15:23164420 A>G | 5'Flank (SNP) | VAF 4/12 reads (33%) | called by mutect2, varscan2
- RNF125 | c.319-36del | Intron (DEL) | VAF 28/77 reads (36%) | called by mutect2, pindel, varscan2
- RP1 | c.*41dup | 3'UTR (INS) | VAF 15/57 reads (26%) | catalogued as rs774193905; called by mutect2, pindel, varscan2
- RPL3 | c.366-170C>T | Intron (SNP) | VAF 19/56 reads (34%) | catalogued as rs1330518912; called by muse, mutect2, varscan2
- SH3PXD2B | c.*4526C>T | 3'UTR (SNP) | VAF 35/106 reads (33%) | called by muse, mutect2, varscan2
- SNAP47 | c.1249-4721G>A | Intron (SNP) | VAF 54/271 reads (20%) | catalogued as rs566590122; called by muse, mutect2, varscan2
- SNORD115-23 | n.10A>G | RNA (SNP) | VAF 78/213 reads (37%) | called by muse, mutect2, varscan2
- SRD5A3 | c.-33dup | 5'UTR (INS) | VAF 56/151 reads (37%) | called by mutect2, pindel, varscan2
- SSPOP | n.4489T>C | RNA (SNP) | VAF 80/205 reads (39%) | catalogued as rs1244283974; called by muse, mutect2, varscan2
- STAB1 | c.4364-40del | Intron (DEL) | VAF 40/95 reads (42%) | called by mutect2, pindel, varscan2
- TAFA5 | c.-21del | 5'UTR (DEL) | VAF 53/190 reads (28%) | catalogued as COSV100387150; called by pindel, varscan2
- TGFBR3 | c.*1838del | 3'UTR (DEL) | VAF 16/38 reads (42%) | catalogued as rs201044103; called by mutect2, varscan2
- TMIE | c.-47C>T | 5'UTR (SNP) | VAF 18/148 reads (12%) | called by muse, mutect2, varscan2
- TTN | c.-63G>A | 5'UTR (SNP) | VAF 27/80 reads (34%) | catalogued as rs1434970080; called by muse, mutect2, varscan2
- UBE3A | c.*31del | 3'UTR (DEL) | VAF 11/29 reads (38%) | catalogued as rs750480224; called by mutect2, varscan2
- UBR2 | c.1281+157G>A | Intron (SNP) | VAF 29/82 reads (35%) | catalogued as rs978399522; called by muse, mutect2, varscan2
- UQCRB | c.*2040_*2041del | 3'UTR (DEL) | VAF 41/155 reads (26%) | called by pindel, varscan2
- XIAP | c.*5630C>T | 3'UTR (SNP) | VAF 38/102 reads (37%) | called by muse, varscan2
- ZFYVE21 | c.190-177T>C | Intron (SNP) | VAF 50/365 reads (14%) | called by muse, mutect2, varscan2
